CPTAC case C3N-01843 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/db515089-ad32-4cdb-805a-3e5a967160a9

Demographics
Sex at birth: female; Race: white; Year of birth: 1948; Vital status: Alive; Country of birth: Ukraine.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 68.8 years (25,136 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 738 days (2.0 years); Progression or recurrence: yes; Days to last follow up: 738 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 1.4 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 10; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 201 days; Disease response: Tumor Free.
- Days to follow up: 738 days (2.0 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 706 days (1.9 years).
- Days to follow up: 738 days (2.0 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 64 kg; Height: 164 cm; BMI: 23.8; Hormonal contraceptive use: Never Used.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 12.5; Cigarettes per day: 10; Tobacco smoking onset year: 1991; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 31.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01843-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Initial weight: 400 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01843-21: Section location: Entire uterine cavity; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3N-01843-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 400 mg.
- Sample C3N-01843-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 380 mg.
- Sample C3N-01843-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 160 mg.
- Sample C3N-01843-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 36 days; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-01843-31, C3N-01843-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01843-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 36 days; Method of sample procurement: Blood Draw.
